Gene-level copy-number profile of tumor specimen C3N-02919-02 from CPTAC case C3N-02919, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 57.9 years (21,151 days).
Specimen C3N-02919-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9217e30b-d119-434a-990f-25a6369d64a2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02919-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/2703153e-f279-432b-a9f9-834fcd3e6a7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 4,893; copy number 2: 52,065; copy number 3: 1,709; copy number 4: 109; copy number 5: 16; copy number 6: 46; copy number 8: 19; copy number 9: 11; copy number 10: 6; copy number 11: 37.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,934,101–29,934,286, 1 gene: HLA-U.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 135 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:30,559,158–31,302,739, 20 genes, copy number 6 (within-gene range 2–6): G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA.
- chr14:35,819,224–38,041,442, 43 genes, copy number 6–8 (within-gene range 4–8): AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517.
- chr14:38,605,255–38,728,481, 2 genes, copy number 6: AL357094.1, KRT8P1.
- chr14:39,031,919–39,212,255, 11 genes, copy number 9: SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1.
- chr14:61,529,128–61,657,964, 1 gene, copy number 10 (within-gene range 2–10): AL355916.3.
- chr14:61,556,273–61,751,099, 5 genes, copy number 10 (within-gene range 2–10): LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3.
- chr14:89,110,148–90,816,479, 37 genes, copy number 11 (within-gene range 4–11): MPPE1P1, FOXN3, AL138478.1, CAP2P1, AL357093.2, AL357093.1, AL356805.1, AL137230.2, FOXN3-AS1, FOXN3-AS2, RN7SKP107, AL137230.1, Y_RNA, RN7SKP255, CHORDC2P, EFCAB11, RAB42P1, TDP1, KCNK13, GLRXP2, Y_RNA, PSMC1, NRDE2, AL161662.1, RPL21P11, AL512791.2, CALM1, AL512791.1, LINC02317, LINC00642, AL096869.3, TTC7B, AL096869.1, AL096869.2, AL139193.1, AL139193.2, AL122020.2.
- chr14:93,138,066–93,788,485, 16 genes, copy number 5: CYB5AP3, MOAP1, TMEM251, AL110118.1, GON7, UBR7, AL132838.1, BTBD7, AL132838.2, UNC79, AL122023.1, COX8C, Y_RNA, RNU6-1258P, AL157858.2, PRIMA1.

Autosomal genes at a single copy (total copy number 1): 2,050. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
